Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9ED, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9ED-01A (Primary Tumor).

Date of surgery :

Left eye enucleation

Macroscopy

The eyeball measures 27 mm main line with a posterior segment of optic nerve of 7 mm. At the section , the tumor seen measures 12 mm main line. A large number of samples have been made for cryopreservation and cytogenetic studies.

Microscopy

The cut end of the optic nerve as well as the optic nerve on his entire course including the optic foramen are free of tumor. An uveal melanoma can be found, developed in the ciliary processes. The tumor is nearly only made with fusiform cells organize in short little bundles, separated by conjunctival vascular septum. The nuclear atypia are moderate. The nuclei are ovoid with a small nucleolus. There are a few mitotic figures. Some of the cells are pigmented. There is no visible endo lymphatic embolus. The tumor infiltrates the thickness of the choroid but does not infiltrates the sclera. The anterior chamber is free.

Conclusion

Melanoma of the choroid of the left eye , originating at the ciliary processes.

Size of the tumor: 12 mm

Infiltration of the choroid.

Sclera free of tumor , optic nerve on his entire course including the cut end free of tumor

ICD O-3

Melanoma spindle cell NOS
8772/3

Site: Ciliary body c69.4

YD 5/10/14

Criteria	Met 12/30/13	Yes	No
ICD-9 Discrepancy			
Dual/Secondary Primary			
Code is (circle)			
Reviewed Initially	ATC	Date reviewed	11/6/14

Source: NCI Genomic Data Commons file 2e6a20a0-087a-4075-b562-39edcb570a28 (TCGA-V4-A9ED.0A53BD62-157E-4D8D-B88A-6ACA3DAD61D0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).